Somatic mutation profile of tumor specimen TCGA-EI-6512-01A (aliquot TCGA-EI-6512-01A-11D-1733-10) from TCGA case TCGA-EI-6512, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma in tubulovillous adenoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 64.4 years (23,537 days).
Specimen TCGA-EI-6512-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd6ce45e-5cea-4bc8-9bc3-ac09e8e2e700.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6512-10A (Blood Derived Normal), aliquot TCGA-EI-6512-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff00178b-9fc3-4ed3-845b-e9e160ea10b5

The open-access MAF lists 137 somatic variants for this specimen: 98 protein-altering or splice-affecting, 35 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 35, Nonsense Mutation 7, Frame Shift Del 5, Intron 2, Frame Shift Ins 2, Splice Site 2, RNA 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 145/224 reads (65%) | catalogued as rs137852216, CM090021, COSV57654256, COSV57668550; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 64/85 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PKD2 | c.2533C>T p.R845* | Nonsense Mutation (SNP) | VAF 31/120 reads (26%) | catalogued as rs369678636, CM003771; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761953570, COSV62326387; called by muse, mutect2, varscan2
- ACTRT1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 127/183 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1057036987, COSV64419795; called by muse, mutect2, varscan2
- ADGRV1 | c.3929C>A p.T1310N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV67996838; called by muse, mutect2, varscan2
- AJAP1 | c.536A>C p.E179A | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.63); catalogued as COSV65449977, COSV65455371; called by muse, mutect2, varscan2
- AMACR | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as rs1386707127, COSV59460282; called by muse, mutect2, varscan2
- ANK3 | c.1388A>G p.N463S | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55086357; called by muse, mutect2, varscan2
- APBA3 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs201048764, COSV57463866; called by muse, mutect2, varscan2
- APC | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as CD058129, CM086469, COSV104379212, COSV57388933; called by muse, mutect2, varscan2
- APC | c.4709del p.D1570Vfs*6 | Frame Shift Del (DEL) | VAF 27/70 reads (39%) | catalogued as COSV57388937; called by mutect2, pindel, varscan2
- ASB17 | c.530del p.N177Tfs*7 | Frame Shift Del (DEL) | VAF 22/134 reads (16%) | catalogued as rs749460467; called by mutect2, varscan2
- ATXN3 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs531719156, COSV61493627; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1273977047, COSV57283196; called by muse, mutect2, varscan2
- C20orf96 | c.751C>T p.R251C (on ENST00000360321 / NM_153269.3; = p.R250C on NM_080571.1) | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs573549117, COSV64404789; called by muse, mutect2, varscan2
- CHD6 | c.6319G>A p.V2107M | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs753612503, COSV100951401; called by muse, mutect2, varscan2
- CRTAC1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as rs374956458; called by muse, mutect2, varscan2
- CTNND2 | c.2087C>A p.S696* | Nonsense Mutation (SNP) | VAF 34/144 reads (24%) | catalogued as COSV58882446, COSV58935372; called by muse, mutect2, varscan2
- DMRTA1 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57925632; called by muse, mutect2, varscan2
- DNAJC9 | c.756dup p.S253Ifs*26 | Frame Shift Ins (INS) | VAF 21/124 reads (17%) | catalogued as rs771072063; called by mutect2, pindel, varscan2
- DOCK1 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1364200071, COSV54763908; called by muse, varscan2
- EBF3 | c.1250G>A p.R417H (on ENST00000355311 / NM_001375392.1; = p.R408H on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs149862226; called by muse, mutect2, varscan2
- ELAC1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 113/166 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53997439; called by muse, mutect2, varscan2
- ELK1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99902418; called by muse, mutect2, varscan2
- EPHB4 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs758697441, COSV62270859; called by muse, mutect2, varscan2
- FAM107B | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); catalogued as rs545803258, COSV51694295; called by muse, mutect2, varscan2
- FAM90A1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as rs778091616, COSV56715351, COSV56715533; called by mutect2, varscan2
- FAT2 | c.6605G>A p.R2202Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1342973239, COSV55820366; called by muse, mutect2, varscan2
- FAT4 | c.14494G>T p.A4832S | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV100630588; called by muse, mutect2, varscan2
- FEZ1 | c.329C>G p.T110R | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV54032203, COSV54032448; called by muse, mutect2, varscan2
- FLG2 | c.3650G>A p.G1217D | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV66174366; called by muse, mutect2, varscan2
- GLUD2 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 173/266 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV60153453; called by muse, mutect2, varscan2
- GRIA2 | c.2446G>A p.V816I | Missense Mutation (SNP) | VAF 123/279 reads (44%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.996); catalogued as COSV52409602; called by muse, mutect2, varscan2
- GRIA3 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM074897, COSV99992248; called by muse, mutect2, varscan2
- HMCN1 | c.3148G>T p.V1050F | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV54948442; called by muse, mutect2, varscan2
- HOXB3 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV57488500; called by muse, mutect2
- IFNAR2 | c.1342A>C p.M448L | Missense Mutation (SNP) | VAF 66/111 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV51618609; called by muse, mutect2, varscan2
- ITSN1 | c.3016+1G>T p.X1006_splice | Splice Site (SNP) | VAF 66/99 reads (67%) | catalogued as COSV66086856; called by muse, mutect2, varscan2
- KCNH7 | c.1487G>T p.W496L | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59816953; called by muse, mutect2, varscan2
- KCNJ1 | c.142A>T p.R48W | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60661993; called by muse, mutect2, varscan2
- KIF5C | c.1450G>T p.V484L | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.847); catalogued as COSV68480177, COSV68484252; called by muse, mutect2, varscan2
- KNDC1 | c.1627G>A p.V543I | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs182563365; called by muse, mutect2, varscan2
- LRRCC1 | c.2864G>T p.S955I | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV64486368; called by muse, mutect2, varscan2
- LRRIQ1 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV67840213; called by muse, mutect2, varscan2
- MAML3 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs935950874, COSV72210390; called by muse, mutect2, varscan2
- MBD5 | c.2762C>A p.S921Y | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV68696077, COSV68699233; called by muse, mutect2, varscan2
- MED1 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV56129228; called by muse, mutect2, varscan2
- MUC16 | c.237G>T p.L79F | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as COSV67500553; called by muse, mutect2, varscan2
- MYCBP2 | c.634+1G>A p.X212_splice (on ENST00000357337; = p.X250_splice on NM_015057.5) | Splice Site (SNP) | VAF 13/88 reads (15%) | catalogued as COSV62042472; called by mutect2, varscan2
- MYO5B | c.5071G>A p.A1691T | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1314742226; called by muse, mutect2
- NBEA | c.8014G>A p.V2672I | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs1422355070, COSV59830002; called by muse, mutect2, varscan2
- NLGN1 | c.2261T>A p.L754H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100848798, COSV100850237, COSV64330434; called by muse, mutect2, varscan2
- NLGN4X | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 62/403 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52040440; called by muse, mutect2, varscan2
- NOC2L | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.741); catalogued as rs372783720; called by muse, mutect2, varscan2
- NR0B1 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as COSV66763798; called by muse, mutect2, varscan2
- NTSR1 | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766108856, COSV65139771; called by muse, mutect2, varscan2
- NXPE3 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as rs746081450, COSV56288684, COSV99839742; called by muse, mutect2, varscan2
- OR2W1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 109/138 reads (79%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs745574396, COSV65851508; called by muse, mutect2, varscan2
- OR7A5 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.32); catalogued as COSV59235784; called by muse, mutect2, varscan2
- PBX1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as COSV100905308, COSV63343818; called by muse, mutect2, varscan2
- PCDHB16 | c.418C>A p.L140I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV53360479, COSV53372571; called by muse, mutect2, varscan2
- PKN2 | c.1405C>A p.Q469K | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV100281851; called by muse, mutect2, varscan2
- PLEKHM1 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372492506; called by muse, mutect2, varscan2
- RAPGEF4 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.984); catalogued as rs773272442, COSV51378958; called by muse, mutect2, varscan2
- RYR1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751622747, COSV62113343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLAMF9 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 26/108 reads (24%) | catalogued as rs182177421; called by muse, mutect2, varscan2
- SLC28A3 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs769712186, COSV66155282; called by muse, mutect2, varscan2
- SLC4A4 | c.394A>G p.I132V (on ENST00000264485 / NM_001098484.3; = p.I88V on NM_003759.4) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV52628652; called by muse, mutect2, varscan2
- SLITRK1 | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65677101, COSV65678037; called by muse, mutect2, varscan2
- SLITRK5 | c.201C>A p.N67K | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV61527223; called by muse, mutect2, varscan2
- SNU13 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV53238828; called by muse, mutect2, varscan2
- SREBF2 | c.2068G>T p.D690Y | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV63332991; called by muse, mutect2, varscan2
- SSX3 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 83/627 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV100035549; called by muse, mutect2, varscan2
- SYT10 | c.95A>G p.E32G | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV57346502; called by muse, mutect2, varscan2
- SYT5 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1457391616, COSV62830419; called by muse, mutect2, varscan2
- TECPR2 | c.3548C>T p.A1183V | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); catalogued as rs146196522; called by muse, mutect2, varscan2
- TENM4 | c.6730C>T p.R2244C | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777521844, COSV53634011; called by muse, mutect2, varscan2
- THEMIS | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 83/111 reads (75%) | catalogued as COSV64074979; called by muse, mutect2, varscan2
- TMEM132D | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV70613849, COSV70624102; called by muse, mutect2, varscan2
- TOPBP1 | c.3811C>T p.Q1271* | Nonsense Mutation (SNP) | VAF 61/142 reads (43%) | catalogued as COSV53443010; called by muse, mutect2, varscan2
- TP53 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs750600586, CM123559, COSV52661339, COSV52708439, COSV53502932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTYH3 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs763565617, COSV51863556; called by muse, mutect2, varscan2
- UBQLNL | c.207A>C p.Q69H | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66493901; called by muse, mutect2, varscan2
- XKR7 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101629312; called by muse, mutect2, varscan2
- YEATS2 | c.3191G>C p.G1064A | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV59373469; called by muse, mutect2, varscan2
- ZEB2 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57957273, COSV57967957; called by muse, mutect2, varscan2
- ZNF184 | c.1115C>T p.T372I | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs1354524644, COSV53006042; called by muse, mutect2, varscan2
- ZNF254 | c.502A>T p.N168Y | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as rs1009984316, COSV61645236; called by muse, mutect2, varscan2
- ZNF418 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs763614043, COSV101269041; called by muse, mutect2, varscan2
- ZNF623 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV71697389; called by muse, mutect2, varscan2
- ZSCAN1 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as rs775413337, COSV56604032; called by muse, mutect2, varscan2
- ADAL | c.651del p.E218Kfs*33 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- DST | c.4496dup p.L1499Ffs*11 (on ENST00000361203 / NM_001374722.1; = p.L1173Ffs*11 on NM_015548.5) | Frame Shift Ins (INS) | VAF 38/119 reads (32%) | called by mutect2, varscan2
- PIK3R1 | c.1336_1380del p.G446_S460del (on ENST00000521381 / NM_181523.3; = p.G176_S190del on NM_181504.4) | In Frame Del (DEL) | VAF 68/198 reads (34%) | called by mutect2, pindel
- TNFRSF1A | c.246_253del p.C84Rfs*52 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | called by mutect2, pindel
- XRN1 | c.364_365del p.L122Sfs*7 | Frame Shift Del (DEL) | VAF 40/214 reads (19%) | called by pindel, varscan2
- ANKK1 | c.2196C>T p.A732= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100393146; called by muse, mutect2, varscan2
- ANKRD30A | c.3123C>T p.A1041= (on ENST00000611781; = p.A985= on NM_052997.2) | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as rs564020781, COSV100654618; called by muse, mutect2
- ATP1A3 | c.2067C>T p.T689= (on ENST00000545399 / NM_001256214.2; = p.T676= on NM_152296.5) | Silent (SNP) | VAF 71/171 reads (42%) | catalogued as rs782556831, COSV57488358; called by muse, mutect2, varscan2
- BASP1 | c.132G>A p.A44= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs753798155, COSV59474295; called by muse, mutect2, varscan2
- CACNA2D1 | c.1545C>A p.I515= | Silent (SNP) | VAF 49/160 reads (31%) | catalogued as COSV100667619; called by muse, mutect2, varscan2
- CSMD2 | c.9681C>T p.S3227= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs372068474, COSV99587365; called by muse, mutect2, varscan2
- CTTN | c.48C>T p.D16= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as rs1316893766, COSV57236624; called by muse, mutect2, varscan2
- CYP11B2 | c.1150C>A p.R384= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs752975169, CM128632, COSV59998259; called by muse, mutect2, varscan2
- EFCAB12 | c.669G>A p.A223= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs745750485, COSV58179292; called by muse, mutect2, varscan2
- ENSA | c.330C>T p.L110= | Silent (SNP) | VAF 74/173 reads (43%) | catalogued as rs770062514, COSV55026381; called by muse, mutect2, varscan2
- FAT2 | c.8778G>A p.A2926= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs374640362, COSV55821401; called by muse, mutect2, varscan2
- FGF23 | c.639C>T p.A213= | Silent (SNP) | VAF 46/53 reads (87%) | catalogued as rs756683570, COSV52978333; called by muse, mutect2, varscan2
- G6PC | c.954C>T p.V318= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as rs372612424, COSV53833246; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDF5 | c.1377G>A p.E459= | Silent (SNP) | VAF 295/416 reads (71%) | catalogued as COSV65503959; called by muse, mutect2, varscan2
- GJB2 | c.237G>A p.L79= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as COSV67010947; called by muse, mutect2, varscan2
- IRGC | c.1050G>A p.S350= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs374269776; called by muse, mutect2, varscan2
- KRT20 | c.246G>A p.A82= | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as rs753053653, COSV51424844; called by muse, mutect2, varscan2
- KRTAP13-3 | c.273T>A p.S91= | Silent (SNP) | VAF 35/50 reads (70%) | catalogued as COSV61879462, COSV61879897, COSV61880010; called by muse, mutect2, varscan2
- LARP7 | c.1693A>C p.R565= | Silent (SNP) | VAF 91/346 reads (26%) | catalogued as COSV60522553; called by muse, varscan2
- MED12 | c.381G>A p.T127= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs202125318, COSV61358732; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- NBEAL2 | c.6258G>A p.A2086= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs371080261, COSV99435199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NECAP2 | c.48C>T p.V16= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs777105429, COSV59189084; called by muse, mutect2, varscan2
- NPAS3 | c.2088C>T p.G696= (on ENST00000356141 / NM_001164749.2; = p.G664= on NM_022123.3) | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs780878323, COSV60821388; called by muse, mutect2, varscan2
- PCDHGB5 | c.2052G>T p.L684= | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as COSV54050976; called by muse, mutect2, varscan2
- PCIF1 | c.1437C>T p.F479= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs746785031, COSV59820781; called by muse, mutect2, varscan2
- SDK2 | c.6156C>T p.S2052= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs200589595, COSV66198659; called by muse, mutect2, varscan2
- SLC8A3 | c.2037G>A p.T679= (on ENST00000381269 / NM_183002.3; = p.T677= on NM_033262.4) | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as rs781373778, COSV53692012, COSV99385974; called by muse, mutect2, varscan2
- SRPK3 | c.219C>T p.D73= | Silent (SNP) | VAF 39/221 reads (18%) | catalogued as rs782773773, COSV54210567; called by muse, mutect2, varscan2
- STRIP1 | c.1191C>T p.P397= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV63930168; called by muse, mutect2, varscan2
- TNN | c.1956G>A p.V652= | Silent (SNP) | VAF 62/136 reads (46%) | catalogued as rs1397896836, COSV53437666; called by muse, mutect2, varscan2
- TSHZ3 | c.1446C>T p.D482= | Silent (SNP) | VAF 122/324 reads (38%) | catalogued as rs745403920, COSV53664438, COSV53666789; called by muse, mutect2, varscan2
- ZFYVE9 | c.3837C>T p.V1279= | Silent (SNP) | VAF 77/168 reads (46%) | catalogued as rs373689197; called by muse, mutect2, varscan2
- ZNF536 | c.2100C>T p.V700= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs776585198, COSV62824485; called by muse, mutect2, varscan2
- ZNF701 | c.1020G>A p.E340= (on ENST00000301093; = p.E274= on NM_018260.3) | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as rs1344527347, COSV56527581; called by muse, mutect2, varscan2
- ZNF835 | c.1246C>A p.R416= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV73379763, COSV73379808; called by muse, mutect2, varscan2
- KCNIP4 | c.61+251162G>T | Intron (SNP) | VAF 17/45 reads (38%) | catalogued as COSV66203638; called by muse, mutect2, varscan2
- MIR557 | n.38G>A | RNA (SNP) | VAF 44/97 reads (45%) | catalogued as rs770977808; called by muse, mutect2, varscan2
- SGIP1 | c.1571-985C>T | Intron (SNP) | VAF 7/27 reads (26%) | catalogued as rs371206061; called by muse, mutect2, varscan2
- ZNF585B | c.*1G>C | 3'UTR (SNP) | VAF 97/246 reads (39%) | catalogued as COSV100459707; called by muse, mutect2, varscan2
